Somatic mutation profile of tumor specimen TARGET-15-SJMPAL046470-09A.2 (aliquot TARGET-15-SJMPAL046470-09A.2-01D) from TARGET case TARGET-15-SJMPAL046470, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.7 years (4,623 days).
Specimen TARGET-15-SJMPAL046470-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bf74e27-50d2-4658-8157-7ea6640424d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL046470-15A (Fibroblasts from Bone Marrow Normal), aliquot TARGET-15-SJMPAL046470-15A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0933f381-625a-4143-9f64-a11827303d22

The open-access MAF lists 37 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Nonsense Mutation 3, Intron 3, 3'UTR 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCAS1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.97); PolyPhen benign (0.127); catalogued as rs755981737, COSV65090190; called by muse, varscan2
- CELSR2 | c.2210C>A p.T737K | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99603183; called by muse, mutect2
- CNOT8 | c.854C>A p.A285E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs901380942; called by muse, mutect2
- EFCAB6 | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 40/65 reads (62%) | catalogued as rs772599532, COSV53060948; called by muse, mutect2, varscan2
- FRMD6 | c.442C>T p.R148* (on ENST00000344768 / NM_001267046.2; = p.R140* on NM_152330.4) | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as rs771992156; called by muse, mutect2
- GAS6 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs193064751; called by muse, mutect2, varscan2
- OR10C1 | c.802G>A p.D268N (on ENST00000622521; = p.D266N on NM_013941.3) | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV65822153, COSV65822361; called by muse, mutect2, varscan2
- OR10G7 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs746856435, COSV100389830, COSV57865473, COSV57865543; called by muse, mutect2, varscan2
- PIP4K2A | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60541332; called by muse, mutect2, varscan2
- PRKG1 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.162); catalogued as rs777385159, COSV64790700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTCHD1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs757295075, COSV101037691; called by muse, varscan2
- AASDH | c.2029G>T p.A677S | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.011); called by muse, mutect2
- ASXL1 | c.1879dup p.A627Gfs*8 | Frame Shift Ins (INS) | VAF 30/45 reads (67%) | called by mutect2, varscan2
- CCDC157 | c.1571C>A p.T524N | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- EZH2 | c.1589G>A p.C530Y (on ENST00000460911 / NM_001203247.2; = p.C535Y on NM_004456.5) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GEMIN4 | c.2449G>T p.A817S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HYDIN | c.12296G>T p.G4099V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH9 | c.622G>T p.G208* | Nonsense Mutation (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2, varscan2
- OR51E2 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2
- PRAMEF15 | c.1343G>C p.R448T | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RPL27A | c.139A>G p.K47E | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SOX5 | c.1588G>T p.D530Y | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM178A | c.860C>A p.A287E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.102); called by muse, mutect2
- YTHDF1 | c.1469G>T p.R490L | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADPRM | c.741C>T p.D247= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs368408429, COSV59379608; called by muse, varscan2
- CDH5 | c.2154C>T p.H718= | Silent (SNP) | VAF 21/46 reads (46%) | called by muse, varscan2
- CXCR4 | c.771T>C p.I257= | Silent (SNP) | VAF 60/131 reads (46%) | catalogued as rs146627075; called by muse, mutect2, varscan2
- EVX1 | c.1020C>T p.G340= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs758781357; called by muse, varscan2
- FMO3 | c.1110C>A p.G370= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- MYO18B | c.1212C>T p.N404= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs772481621; called by muse, mutect2, varscan2
- NLRP9 | c.2412C>T p.L804= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs746094792, COSV60466837; called by muse, mutect2, varscan2
- PIGO | c.2889G>A p.L963= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs959471469; called by muse, mutect2, varscan2
- F12 | c.1388-34G>T | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- MIR513C | n.30G>A | RNA (SNP) | VAF 37/121 reads (31%) | catalogued as rs782290927; called by muse, mutect2, varscan2
- MROH8 | c.370+2409G>T | Intron (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- PARK7 | c.*6C>T | 3'UTR (SNP) | VAF 37/87 reads (43%) | catalogued as rs532144863; called by muse, mutect2, varscan2
- SNX22 | c.360-21_360-20del | Intron (DEL) | VAF 20/50 reads (40%) | catalogued as rs748176970; called by mutect2, varscan2
